Somatic mutation profile of tumor specimen TCGA-78-7156-01A (aliquot TCGA-78-7156-01A-11D-2036-08) from TCGA case TCGA-78-7156, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 62.2 years (22,720 days).
Specimen TCGA-78-7156-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4769f0f-f678-4a7b-9941-f08c4725ea61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7156-10A (Blood Derived Normal), aliquot TCGA-78-7156-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93cd07f3-bf6b-4d35-8c5a-483bd2ce7221

The open-access MAF lists 323 somatic variants for this specimen: 263 protein-altering or splice-affecting, 56 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 56, Nonsense Mutation 23, Splice Site 10, Frame Shift Del 9, Intron 2, In Frame Ins 1, 3'UTR 1, 3'Flank 1, Nonstop Mutation 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MKRN3 | c.482del p.P161Rfs*10 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- STK11 | c.842dup p.L282Afs*3 | Frame Shift Ins (INS) | VAF 11/29 reads (38%) | catalogued as rs121913321; ClinVar: pathogenic; called by mutect2, pindel
- ABCG8 | c.1694C>A p.A565D | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs200919814, COSV99699509; called by muse, mutect2, varscan2
- AC104452.1 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 78/195 reads (40%) | catalogued as COSV99864435, COSV99864695; called by muse, mutect2, varscan2
- ACKR1 | c.77G>A p.W26* | Nonsense Mutation (SNP) | VAF 115/201 reads (57%) | catalogued as COSV100929495; called by muse, mutect2, varscan2
- ACOT7 | c.1075G>A p.E359K (on ENST00000377855 / NM_181864.3; = p.E349K on NM_007274.4) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100830159; called by muse, mutect2, varscan2
- ADAMTS3 | c.2377G>C p.E793Q | Missense Mutation (SNP) | VAF 144/344 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99710426; called by muse, mutect2, varscan2
- ADCY4 | c.3223A>C p.T1075P | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs745883237, COSV100156266; called by muse, mutect2, varscan2
- ADIPOR2 | c.1036C>A p.H346N | Missense Mutation (SNP) | VAF 25/634 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV100840051, COSV63947410; called by muse, mutect2
- AEBP1 | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as rs1259084830, COSV99788516; called by muse, mutect2
- AHNAK | c.3793C>T p.P1265S | Missense Mutation (SNP) | VAF 313/889 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.79); catalogued as COSV99946088; called by muse, mutect2, varscan2
- AKR1C1 | c.204G>C p.K68N | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV101080394; called by muse, mutect2, varscan2
- AKR7A3 | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV100853793; called by muse, mutect2, varscan2
- AKT2 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs764512283, COSV100251450; called by muse, mutect2
- ALG10B | c.700C>G p.L234V | Missense Mutation (SNP) | VAF 37/376 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as COSV100439817, COSV58142197; called by muse, mutect2, varscan2
- AMPD1 | c.1561G>C p.E521Q | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV100814896, COSV62415028; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4386G>C p.K1462N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV51855915, COSV99782372; called by muse, mutect2, varscan2
- ANKRD26 | c.1069C>G p.L357V | Missense Mutation (SNP) | VAF 21/272 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV101066107; called by muse, mutect2
- APBB1IP | c.110A>T p.N37I | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100774318; called by muse, mutect2, varscan2
- ARGFX | c.603T>A p.S201R | Missense Mutation (SNP) | VAF 112/293 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1415088769, COSV100544080; called by muse, mutect2, varscan2
- ARID1A | c.5293G>T p.E1765* | Nonsense Mutation (SNP) | VAF 81/212 reads (38%) | catalogued as COSV61375110, COSV61375644; called by muse, mutect2, varscan2
- ATP2C1 | c.1071G>C p.K357N | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.248); catalogued as COSV100146368, COSV60763171; called by muse, mutect2, varscan2
- BRIP1 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as COSV51996384; called by muse, mutect2
- BUB1B | c.2390C>G p.S797C | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.701); catalogued as COSV99806647; called by muse, mutect2, varscan2
- C8A | c.1097-1G>T p.X366_splice | Splice Site (SNP) | VAF 125/311 reads (40%) | catalogued as COSV100776458; called by muse, mutect2, varscan2
- C9orf72 | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 82/130 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV101186493; called by muse, mutect2, varscan2
- CARD11 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1298741148, COSV67802261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAT | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99573132; called by muse, mutect2, varscan2
- CCDC57 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs373916021; called by muse, mutect2, varscan2
- CCR4 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs762113496, COSV58381447; called by muse, mutect2, varscan2
- CDC23 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 141/323 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.189); catalogued as COSV101202981; called by muse, mutect2, varscan2
- CDH17 | c.1786C>A p.L596M | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.949); catalogued as COSV99217034; called by muse, mutect2, varscan2
- CDH20 | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 13/379 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV99404585; called by muse, mutect2
- CDH7 | c.1976G>T p.G659V | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474589509, COSV100541133; called by muse, mutect2, varscan2
- CEACAM7 | c.394A>C p.N132H | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV99137152; called by muse, mutect2, varscan2
- CENPJ | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 43/387 reads (11%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.536); catalogued as COSV101121474; called by muse, mutect2, varscan2
- CFAP206 | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV99739236; called by muse, mutect2, varscan2
- CHRNA2 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV99531971; called by muse, mutect2, varscan2
- CIAO3 | c.750G>C p.K250N | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99284605; called by muse, mutect2, varscan2
- CIPC | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV100694428; called by muse, mutect2
- CLGN | c.50T>C p.I17T | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100346440; called by muse, mutect2, varscan2
- CLIP4 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1225408246, COSV100191562; called by muse, mutect2
- CLSPN | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as COSV99230429; called by muse, mutect2
- CNGB3 | c.2185G>C p.E729Q | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as COSV100181459; called by muse, mutect2, varscan2
- CNNM1 | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.334); catalogued as COSV100763777; called by muse, mutect2, varscan2
- CREBBP | c.4648G>A p.E1550K | Missense Mutation (SNP) | VAF 9/263 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52118002, COSV52134589; called by muse, mutect2
- CRNKL1 | c.1486G>C p.D496H | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101056897; called by muse, mutect2
- CSF3R | c.1475-1G>A p.X492_splice | Splice Site (SNP) | VAF 39/90 reads (43%) | catalogued as COSV100117408; called by muse, mutect2, varscan2
- CSMD3 | c.3058C>A p.R1020S (on ENST00000297405 / NM_001363185.1; = p.R916S on NM_052900.3) | Missense Mutation (SNP) | VAF 86/225 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.258); catalogued as COSV99827650; called by muse, mutect2, varscan2
- CSNK1A1 | c.88del p.D30Tfs*16 | Frame Shift Del (DEL) | VAF 69/190 reads (36%) | catalogued as COSV55796034; called by mutect2, pindel, varscan2
- CYLC1 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV100254205; called by muse, mutect2, varscan2
- CYP26B1 | c.935T>C p.L312P | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50014759; called by muse, mutect2, varscan2
- DBNDD1 | c.382G>C p.E128Q (on ENST00000002501 / NM_001042610.3; = p.E148Q on NM_024043.3) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV99136417, COSV99136541; called by muse, mutect2
- DDX10 | c.758C>A p.S253* | Nonsense Mutation (SNP) | VAF 16/276 reads (6%) | catalogued as COSV100489159; called by muse, mutect2
- DEPDC1 | c.1445G>T p.G482V | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.368); catalogued as COSV100920224; called by muse, mutect2, varscan2
- DKK2 | c.171G>T p.M57I | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99568298; called by muse, mutect2, varscan2
- DLG5 | c.5553G>C p.Q1851H | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100967314; called by muse, mutect2
- DNAH11 | c.6280A>G p.M2094V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV99080630; called by muse, mutect2, varscan2
- DNAJA2 | c.348G>C p.M116I | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV100398808; called by muse, mutect2
- DNAJB14 | c.1024A>T p.M342L | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100508320; called by muse, mutect2, varscan2
- DOCK10 | c.1764G>C p.K588N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99288112; called by muse, mutect2, varscan2
- DOT1L | c.2044G>T p.E682* | Nonsense Mutation (SNP) | VAF 39/60 reads (65%) | catalogued as COSV101288540; called by muse, mutect2, varscan2
- DPY19L2 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.726); catalogued as COSV100116589; called by muse, mutect2, varscan2
- DYSF | c.3196_3197insCGGATG p.E1065_G1066insAD | In Frame Ins (INS) | VAF 34/139 reads (24%) | catalogued as CI105954; called by pindel, varscan2*
- ECT2 | c.1217C>T p.S406L (on ENST00000392692 / NM_001349098.2; = p.S375L on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV99221021; called by muse, mutect2
- EIF3K | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 114/272 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99942918; called by muse, mutect2, varscan2
- EIF4G3 | c.255T>A p.Y85* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as COSV99943543; called by muse, mutect2, varscan2
- ELP3 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1266456486, COSV56461357; called by muse, mutect2
- EMP2 | c.347A>T p.Y116F | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100852775; called by muse, mutect2, varscan2
- ENTPD5 | c.556C>G p.Q186E | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.764); catalogued as COSV100592158; called by muse, mutect2, varscan2
- EPHB6 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844168; called by muse, mutect2
- ERG | c.871G>A p.E291K (on ENST00000398919 / NM_001243428.1; = p.E267K on NM_004449.4) | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs1479045605, COSV99901355; called by muse, mutect2, varscan2
- ESPNL | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV100547648, COSV100547984; called by muse, mutect2
- FADS3 | c.1337G>T p.*446Lext*72 | Nonstop Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99605164; called by muse, mutect2, varscan2
- FAM120A | c.2644C>T p.Q882* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99464752; called by mutect2, varscan2
- FAM3B | c.483A>C p.T161= | Splice Region (SNP) | VAF 61/198 reads (31%) | catalogued as rs776326598, COSV100783719; called by muse, mutect2, varscan2
- FAT4 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101272139; called by muse, mutect2
- GAB2 | c.199G>A p.E67K (on ENST00000361507 / NM_080491.3; = p.E29K on NM_012296.3) | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100416346; called by muse, mutect2, varscan2
- GABRA1 | c.622G>T p.V208L | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99195744; called by muse, mutect2, varscan2
- GCNT4 | c.1159C>G p.L387V | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV100466309; called by muse, mutect2, varscan2
- GFAP | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV53650875, COSV99493081, COSV99493104; called by muse, mutect2, varscan2
- GMEB2 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99823497; called by muse, mutect2
- GNA15 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as COSV99505085; called by muse, mutect2, varscan2
- GRIN2A | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 69/126 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0.019); catalogued as rs765986049, COSV58053418; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GRIN2B | c.1795T>A p.S599T | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV101662943; called by muse, mutect2, varscan2
- GRM1 | c.2578G>T p.V860F | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV99264688; called by muse, mutect2, varscan2
- GRM8 | c.960G>T p.Q320H | Missense Mutation (SNP) | VAF 95/247 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100281302; called by muse, mutect2, varscan2
- GSDMB | c.236G>A p.G79D | Missense Mutation (SNP) | VAF 80/144 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs1311936830, COSV100522645; called by muse, mutect2, varscan2
- H3-4 | c.143C>A p.A48E | Missense Mutation (SNP) | VAF 173/323 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV100797362; called by muse, varscan2
- HASPIN | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778788646, COSV53993857; called by muse, mutect2
- HECW2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53669539; called by muse, mutect2
- HLCS | c.2088G>T p.Q696H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99292964; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.259G>C p.D87H (on ENST00000354667 / NM_031243.3; = p.D75H on NM_002137.4) | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61159727; called by muse, mutect2
- HRH2 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV51572695, COSV51572738; called by muse, mutect2, varscan2
- HS3ST6 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1288536587, COSV99562597; called by muse, mutect2
- HTRA1 | c.610G>T p.G204W | Missense Mutation (SNP) | VAF 98/261 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934700; called by muse, mutect2, varscan2
- IGKV1D-42 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747084673; called by muse, mutect2, varscan2
- IQGAP2 | c.4495C>G p.Q1499E | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.173); catalogued as rs972879133, COSV99166803; called by muse, mutect2
- ITLN1 | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 102/206 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs1259389444, COSV100406139; called by muse, mutect2, varscan2
- ITPR2 | c.1154C>G p.S385* | Nonsense Mutation (SNP) | VAF 6/150 reads (4%) | catalogued as COSV101189866; called by muse, mutect2
- KCNQ2 | c.2555C>A p.P852Q (on ENST00000359125 / NM_172107.4; = p.P824Q on NM_004518.6) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV100609924, COSV100610594; called by muse, mutect2, varscan2
- KCNT1 | c.1116C>A p.N372K (on ENST00000488444; = p.N391K on NM_020822.3) | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV99705177; called by muse, mutect2
- KDM2B | c.2491C>T p.L831F | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV100997272; called by muse, mutect2, varscan2
- KLHL22 | c.910G>T p.G304W | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100185867; called by muse, mutect2, varscan2
- KMT2A | c.8861A>G p.D2954G | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as COSV100628179; called by muse, mutect2, varscan2
- KRT13 | c.416G>A p.W139* | Nonsense Mutation (SNP) | VAF 82/131 reads (63%) | catalogued as COSV99877262; called by muse, mutect2, varscan2
- KRT14 | c.221G>T p.S74I | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.34); PolyPhen benign (0.193); catalogued as COSV99390926; called by muse, mutect2, varscan2
- KRTAP5-5 | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.562); catalogued as COSV101294154; called by muse, varscan2
- LAX1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV100920003; called by muse, mutect2, varscan2
- LENG9 | c.1422G>C p.E474D | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as COSV100002717; called by muse, mutect2, varscan2
- LILRA2 | c.569G>C p.R190T | Missense Mutation (SNP) | VAF 123/300 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV99252942; called by muse, mutect2, varscan2
- LONP1 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100638548; called by muse, mutect2, varscan2
- LRFN2 | c.2041G>A p.G681R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.537); catalogued as rs539211841, COSV100599207, COSV57834563; called by muse, mutect2, varscan2
- LRP4 | c.5428G>T p.V1810L | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV101066351; called by muse, mutect2, varscan2
- LRRC3 | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV52399260, COSV99381714; called by muse, mutect2
- LRRC37A3 | c.4079C>A p.S1360* | Nonsense Mutation (SNP) | VAF 14/278 reads (5%) | catalogued as COSV100140901; called by muse, mutect2
- LRRC66 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV100602853; called by muse, mutect2, varscan2
- MACF1 | c.3568C>T p.L1190F | Missense Mutation (SNP) | VAF 93/258 reads (36%) | catalogued as COSV100483055; called by muse, mutect2, varscan2
- MAMDC2 | c.1023C>A p.S341R | Missense Mutation (SNP) | VAF 92/239 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as COSV101015306; called by muse, mutect2, varscan2
- MAP3K12 | c.775A>T p.K259* | Nonsense Mutation (SNP) | VAF 208/543 reads (38%) | catalogued as COSV99913020; called by muse, mutect2, varscan2
- MDGA2 | c.2630T>A p.L877* (on ENST00000399232 / NM_001113498.2; = p.L579* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 93/269 reads (35%) | catalogued as COSV100636515; called by muse, mutect2, varscan2
- MED12 | c.2792G>C p.R931P | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100376640; called by muse, mutect2, varscan2
- MED23 | c.1345C>T p.H449Y | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100644810; called by muse, mutect2
- MEDAG | c.773G>T p.S258I | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs181484496, COSV100995228; called by muse, mutect2, varscan2
- MEPE | c.643C>A p.R215S | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as COSV100734877; called by muse, mutect2, varscan2
- MGA | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 37/72 reads (51%) | catalogued as COSV54948772; called by muse, mutect2, varscan2
- MGA | c.5605C>G p.Q1869E (on ENST00000219905 / NM_001164273.1; = p.Q1660E on NM_001080541.2) | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54960661, COSV99578882; called by muse, mutect2, varscan2
- MIA3 | c.3280C>G p.H1094D | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100719346; called by muse, mutect2
- MRGPRX1 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 113/458 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV57106647, COSV57108814; called by muse, mutect2, varscan2
- MTMR1 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 62/89 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100953065; called by muse, varscan2
- MTUS2 | c.2134G>T p.G712* | Nonsense Mutation (SNP) | VAF 45/112 reads (40%) | catalogued as COSV101462112, COSV70920456; called by muse, mutect2, varscan2
- MYH13 | c.1259A>T p.Q420L | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99352720; called by muse, mutect2, varscan2
- MYO1H | c.1694C>A p.A565D | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.419); catalogued as COSV100183208; called by muse, mutect2, varscan2
- MYOZ1 | c.95T>C p.L32S | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV100831801; called by muse, mutect2
- NBPF15 | c.1992G>T p.M664I | Missense Mutation (SNP) | VAF 273/1015 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs1190974312; called by muse, mutect2, varscan2
- NDUFB5 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99372477; called by muse, mutect2
- NEPRO | c.1460G>T p.W487L | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.058); catalogued as COSV99868255; called by muse, mutect2, varscan2
- NRCAM | c.2548G>T p.G850W (on ENST00000379028 / NM_001371124.1; = p.G834W on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100694372; called by muse, mutect2, varscan2
- NRP2 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99783665; called by muse, mutect2
- NRXN1 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV101276963; called by muse, mutect2, varscan2
- NUP155 | c.3256G>A p.E1086K (on ENST00000231498 / NM_153485.3; = p.E1027K on NM_004298.4) | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774103498, COSV99192300; called by muse, mutect2
- NUTM1 | c.3310C>A p.L1104M | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV100148868; called by muse, mutect2, varscan2
- OLFM3 | c.1368G>A p.W456* (on ENST00000338858 / NM_001288821.1; = p.W436* on NM_058170.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/177 reads (5%) | catalogued as COSV58797965; called by muse, mutect2
- OR10C1 | c.266G>T p.G89V (on ENST00000622521; = p.G87V on NM_013941.3) | Missense Mutation (SNP) | VAF 85/236 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV101010802; called by muse, mutect2, varscan2
- OR10G7 | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV100389807; called by muse, mutect2, varscan2
- OR11H6 | c.722G>T p.R241I | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV100209735; called by muse, mutect2, varscan2
- OR14K1 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99315006; called by muse, mutect2, varscan2
- OR2G3 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 162/289 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180505, COSV60681697; called by muse, mutect2, varscan2
- OR2W1 | c.478T>A p.C160S | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.214); catalogued as rs1045217250, COSV101013899; called by muse, mutect2, varscan2
- OR4C16 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 155/390 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs781765999, COSV100113900; called by muse, mutect2, varscan2
- OR4C16 | c.254del p.L85* | Frame Shift Del (DEL) | VAF 165/528 reads (31%) | catalogued as COSV58943383; called by mutect2, pindel, varscan2
- OR4K2 | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 67/1257 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV100064207, COSV53851510; called by muse, mutect2
- OR51V1 | c.919C>A p.L307I | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100343271; called by muse, mutect2, varscan2
- OR5AS1 | c.145G>T p.V49F | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV100546187; called by muse, mutect2, varscan2
- OR9K2 | c.530G>T p.G177V (on ENST00000305377; = p.G155V on NM_001005243.1) | Missense Mutation (SNP) | VAF 101/248 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100543755, COSV100543867; called by muse, mutect2, varscan2
- OR9Q2 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV100285357, COSV100285569; called by muse, mutect2, varscan2
- OSBPL3 | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV100513804; called by muse, mutect2, varscan2
- OTUD7A | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV61043465; called by muse, mutect2, varscan2
- OXER1 | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99685271; called by muse, mutect2, varscan2
- PCDH17 | c.1432G>T p.V478L | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV100931479, COSV100931533; called by muse, mutect2, varscan2
- PCDHA2 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 133/318 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.781); catalogued as COSV100973663; called by muse, mutect2, varscan2
- PCDHA7 | c.1697T>A p.L566Q | Missense Mutation (SNP) | VAF 106/276 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100971287; called by muse, mutect2, varscan2
- PCDHB12 | c.739T>A p.Y247N | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53395503, COSV99507127; called by muse, mutect2
- PCDHB2 | c.784C>A p.Q262K | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); catalogued as COSV99522905; called by muse, mutect2, varscan2
- PCDHB4 | c.1832C>A p.P611H | Missense Mutation (SNP) | VAF 99/243 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99521927; called by muse, mutect2, varscan2
- PLB1 | c.556-1G>C p.X186_splice | Splice Site (SNP) | VAF 25/81 reads (31%) | catalogued as rs751689772, COSV100577873; called by muse, mutect2, varscan2
- PLCB1 | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100569789; called by muse, mutect2, varscan2
- PPA1 | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100949864; called by muse, mutect2, varscan2
- PRB4 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 147/394 reads (37%) | catalogued as COSV54399052, COSV99686384; called by muse, mutect2, varscan2
- PRDM10 | c.2113G>A p.D705N | Missense Mutation (SNP) | VAF 24/534 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs1231766811, COSV100456616; called by muse, mutect2
- PRUNE2 | c.5854G>A p.E1952K | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.092); catalogued as COSV65044587; called by muse, mutect2
- PTBP2 | c.935C>T p.P312L (on ENST00000426398 / NM_001300986.2; = p.P304L on NM_021190.4) | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100930184, COSV64624879; called by muse, mutect2
- PTCHD3 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.721); catalogued as COSV101438871; called by muse, mutect2, varscan2
- PTPN5 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as COSV62124602, COSV62129528; called by muse, mutect2
- PTX4 | c.289G>T p.V97L (on ENST00000447419 / NM_001328608.2; = p.V92L on NM_001013658.1) | Missense Mutation (SNP) | VAF 93/357 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99560251; called by muse, mutect2, varscan2
- PWP1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV101338789; called by muse, mutect2, varscan2
- PXDNL | c.1697C>T p.T566I | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.326); catalogued as COSV100682189; called by muse, mutect2, varscan2
- QTRT1 | c.682G>T p.G228W | Missense Mutation (SNP) | VAF 68/112 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748388439, COSV51550332, COSV99139017; called by muse, mutect2, varscan2
- RAP1GAP | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV99264855; called by muse, mutect2, varscan2
- REG1A | c.198C>A p.N66K | Missense Mutation (SNP) | VAF 104/256 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.491); catalogued as COSV99286686; called by muse, mutect2, varscan2
- RFTN1 | c.1091G>A p.S364N | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100488955; called by muse, mutect2
- RFX7 | c.1969C>T p.P657S (on ENST00000559447 / NM_001368074.1; = p.P754S on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.022); catalogued as COSV100428308; called by muse, mutect2, varscan2
- RIPK1 | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99454147; called by muse, mutect2, varscan2
- RP1L1 | c.4813C>G p.Q1605E | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.32); catalogued as COSV101223020; called by muse, mutect2, varscan2
- RPUSD2 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); catalogued as COSV100225115, COSV59765909; called by muse, mutect2, varscan2
- RPUSD3 | c.132G>C p.Q44H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV101094648; called by muse, mutect2
- RRP8 | c.1154+1G>T p.X385_splice | Splice Site (SNP) | VAF 59/178 reads (33%) | catalogued as COSV99601825, COSV99602057; called by muse, mutect2, varscan2
- RSPH10B2 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 129/614 reads (21%) | catalogued as COSV99786000; called by muse, mutect2, varscan2
- SACS | c.4438G>T p.E1480* | Nonsense Mutation (SNP) | VAF 64/171 reads (37%) | catalogued as COSV66547391; called by muse, mutect2, varscan2
- SAFB2 | c.1498G>C p.V500L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.048); catalogued as COSV99385460; called by muse, mutect2, varscan2
- SCYL1 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 41/91 reads (45%) | catalogued as COSV99533878; called by muse, mutect2, varscan2
- SDHA | c.1663G>T p.G555* | Nonsense Mutation (SNP) | VAF 68/186 reads (37%) | catalogued as rs1392860800, COSV99371309; called by muse, mutect2, varscan2
- SERPINB2 | c.694G>T p.V232L | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100208239; called by muse, mutect2, varscan2
- SLC16A6 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517212; called by muse, mutect2
- SLC4A3 | c.1912G>T p.E638* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as COSV99812547; called by muse, mutect2, varscan2
- SLC4A3 | c.3211G>T p.D1071Y | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV99812549; called by muse, mutect2, varscan2
- SLC5A10 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.378); catalogued as COSV100524873; called by muse, mutect2, varscan2
- SLC5A12 | c.1379C>A p.P460H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101237613; called by muse, mutect2, varscan2
- SLCO2A1 | c.1262C>G p.S421C | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100188729; called by muse, mutect2, varscan2
- SLITRK2 | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.068); catalogued as COSV100157426; called by muse, mutect2, varscan2
- SLTM | c.2828G>A p.G943E | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); catalogued as COSV100998581; called by muse, mutect2
- SMARCA1 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 116/142 reads (82%) | catalogued as rs763343505, COSV64412759; called by muse, mutect2, varscan2
- SMR3B | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs781338160, COSV100513334; called by muse, mutect2, varscan2
- SMYD5 | c.893A>G p.E298G | Missense Mutation (SNP) | VAF 128/336 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.185); catalogued as rs200366462, COSV99240148; called by muse, mutect2, varscan2
- SNRPD1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV55932668; called by muse, mutect2, varscan2
- SOX5 | c.206C>A p.P69Q | Missense Mutation (SNP) | VAF 210/535 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV100506223; called by muse, mutect2, varscan2
- SOX6 | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 119/342 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV100321440; called by muse, mutect2, varscan2
- SPHKAP | c.4743G>T p.K1581N (on ENST00000392056 / NM_001142644.2; = p.K1552N on NM_030623.3) | Missense Mutation (SNP) | VAF 86/228 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100763801; called by muse, mutect2, varscan2
- SPTA1 | c.5747C>G p.A1916G | Missense Mutation (SNP) | VAF 288/504 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.539); catalogued as COSV100934509; called by muse, mutect2, varscan2
- SSH1 | c.2605G>T p.G869C | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100425382; called by muse, mutect2, varscan2
- STAG2 | c.3467+1G>A p.X1156_splice | Splice Site (SNP) | VAF 37/83 reads (45%) | catalogued as COSV54368052, COSV54370359; called by muse, mutect2, varscan2
- STAG2 | c.3490G>T p.E1164* | Nonsense Mutation (SNP) | VAF 20/147 reads (14%) | catalogued as COSV54373622; called by muse, mutect2, varscan2
- SULF2 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV100737047; called by muse, mutect2, varscan2
- SULT6B1 | c.892G>A p.E298K (on ENST00000535679 / NM_001367551.1; = p.E260K on NM_001032377.2) | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs772460482, COSV99573046; called by muse, mutect2, varscan2
- TAF1L | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99644243; called by muse, mutect2
- TATDN2 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 36/343 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.127); catalogued as COSV99813378; called by muse, mutect2, varscan2
- TC2N | c.904C>G p.L302V | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV61748095; called by muse, mutect2
- TCHH | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 47/556 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100914872, COSV64272629; called by muse, mutect2
- THBS2 | c.2404G>C p.D802H | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100827692, COSV64682160; called by muse, mutect2
- THOC2 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99832911; called by muse, mutect2, varscan2
- THSD4 | c.1698G>C p.R566S | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV99964752; called by muse, mutect2, varscan2
- TMEM120B | c.68A>T p.Q23L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs1418071650, COSV100699609; called by muse, mutect2, varscan2
- TNFRSF9 | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV101097156; called by muse, mutect2, varscan2
- TNNC2 | c.333C>G p.I111M | Missense Mutation (SNP) | VAF 13/304 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1360699626, COSV100999444, COSV65332656; called by muse, mutect2
- TRAPPC4 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV100421484; called by muse, mutect2, varscan2
- TREM1 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs1328482154, COSV99776101; called by muse, mutect2, varscan2
- TRMT5 | c.11+1G>T p.X4_splice | Splice Site (SNP) | VAF 26/94 reads (28%) | catalogued as COSV99711960; called by muse, mutect2, varscan2
- TRPM2 | c.1103A>T p.N368I | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100308327; called by muse, mutect2, varscan2
- UBAP2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV100671030; called by muse, mutect2, varscan2
- UGP2 | c.692A>G p.Y231C | Missense Mutation (SNP) | VAF 129/297 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV100451535; called by muse, mutect2, varscan2
- UNC13C | c.2237C>A p.S746Y | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV52878561, COSV99512989; called by muse, mutect2, varscan2
- UNC45B | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99268330; called by muse, mutect2, varscan2
- URI1 | c.1585G>T p.A529S | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100368888; called by muse, mutect2, varscan2
- UTP20 | c.2329G>A p.D777N | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1440346893, COSV99880975; called by muse, mutect2
- UTY | c.556-2A>T p.X186_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100229405; called by mutect2, varscan2
- WDR70 | c.908C>G p.S303* | Nonsense Mutation (SNP) | VAF 5/109 reads (5%) | catalogued as COSV54268140; called by muse, mutect2
- WSCD2 | c.615C>A p.S205R | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV99774193; called by muse, mutect2, varscan2
- XRCC6 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.524); catalogued as COSV100777795; called by muse, mutect2, varscan2
- YARS2 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.806); catalogued as rs768368005, COSV100256331; called by muse, varscan2
- ZC3HAV1 | c.500C>G p.P167R | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.317); catalogued as COSV99648320; called by muse, mutect2, varscan2
- ZFYVE26 | c.6786+1G>T p.X2262_splice | Splice Site (SNP) | VAF 248/575 reads (43%) | catalogued as COSV100720160; called by muse, mutect2, varscan2
- ZHX2 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100072671; called by muse, mutect2, varscan2
- ZIC4 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.354); catalogued as COSV101267866; called by muse, mutect2, varscan2
- ZNF212 | c.862C>G p.P288A | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100242299; called by muse, mutect2, varscan2
- ZNF512 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs751052657, COSV100820701; called by muse, mutect2, varscan2
- ZNF518B | c.2337G>T p.R779S | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100456587; called by muse, mutect2, varscan2
- ZNF578 | c.275G>C p.R92T | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV101405019; called by muse, mutect2
- ZNF592 | c.423C>A p.F141L | Missense Mutation (SNP) | VAF 43/399 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100245963, COSV55436518; called by muse, mutect2, varscan2
- ZNF646 | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as rs1322307293; called by muse, mutect2
- CAPN9 | c.706-1G>C p.X236_splice | Splice Site (SNP) | VAF 10/312 reads (3%) | called by muse, mutect2
- COL11A1 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2
- FTSJ1 | c.443_444delinsT p.K148Ifs*16 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | called by pindel, varscan2*
- IGHG1 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 129/352 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- IGKV1D-42 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- KCNQ4 | c.1853G>T p.R618L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- KEAP1 | c.1430del p.G477Afs*23 | Frame Shift Del (DEL) | VAF 44/80 reads (55%) | called by mutect2, pindel, varscan2
- MEIOC | c.1137G>C p.Q379H | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- NDUFA5 | c.282G>A p.M94I | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.743); called by muse, mutect2
- OR11H12 | c.556_557del p.P186Kfs*4 | Frame Shift Del (DEL) | VAF 45/450 reads (10%) | called by mutect2, pindel, varscan2
- PHF23 | c.353_355delinsTT p.R118Lfs*14 | Frame Shift Del (DEL) | VAF 68/309 reads (22%) | called by pindel, varscan2*
- SLC18A3 | c.717del p.G240Afs*9 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- STAG2 | c.1992del p.K664Nfs*28 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- UBE2NL | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.117); called by muse, mutect2
- ACD | c.1533C>T p.L511= (on ENST00000620338; = p.L422= on NM_022914.3) | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as COSV99537496; called by muse, mutect2
- ADAMTS12 | c.4047G>T p.A1349= | Silent (SNP) | VAF 80/187 reads (43%) | catalogued as COSV100710419; called by muse, mutect2, varscan2
- ALK | c.1245T>A p.S415= | Silent (SNP) | VAF 65/145 reads (45%) | catalogued as COSV101201450; called by muse, mutect2, varscan2
- AMIGO3 | c.342C>T p.L114= | Silent (SNP) | VAF 21/301 reads (7%) | catalogued as rs987731774, COSV100246472; called by muse, mutect2
- ARHGAP5 | c.4365A>G p.V1455= (on ENST00000345122 / NM_001030055.2; = p.V1454= on NM_001173.3) | Silent (SNP) | VAF 51/116 reads (44%) | catalogued as rs891226920, COSV99391916; called by muse, mutect2, varscan2
- ARRB1 | c.27C>T p.F9= | Silent (SNP) | VAF 59/158 reads (37%) | catalogued as COSV100758067, COSV63574751; called by muse, mutect2, varscan2
- C6orf136 | c.591G>A p.L197= (on ENST00000376473 / NM_001109938.3; = p.L63= on NM_145029.4) | Silent (SNP) | VAF 86/852 reads (10%) | catalogued as COSV99527777; called by muse, mutect2
- CASQ1 | c.147G>C p.V49= | Silent (SNP) | VAF 18/223 reads (8%) | catalogued as COSV100927247; called by muse, mutect2
- CDH10 | c.2133G>T p.R711= | Silent (SNP) | VAF 80/208 reads (38%) | catalogued as COSV100050439, COSV52588107; called by muse, mutect2, varscan2
- CDH8 | c.1311G>A p.R437= | Silent (SNP) | VAF 60/145 reads (41%) | catalogued as rs749684695, COSV100179997; called by muse, mutect2, varscan2
- CEP192 | c.7026G>A p.L2342= | Silent (SNP) | VAF 9/231 reads (4%) | catalogued as COSV100380765; called by muse, mutect2
- CFAP77 | c.123C>T p.I41= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV100524528; called by muse, varscan2
- CFAP77 | c.186C>T p.L62= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as COSV57502955; called by muse, varscan2
- CUL9 | c.1794C>G p.S598= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as COSV99334962; called by muse, mutect2, varscan2
- CYCS | c.120G>A p.K40= | Silent (SNP) | VAF 56/136 reads (41%) | catalogued as rs11548812, COSV99995020; called by muse, mutect2, varscan2
- CYP26B1 | c.936G>T p.L312= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99134314; called by muse, mutect2, varscan2
- DGKG | c.2040C>A p.I680= | Silent (SNP) | VAF 105/276 reads (38%) | catalogued as COSV99402664; called by muse, mutect2, varscan2
- DNAJC16 | c.1696C>A p.R566= | Silent (SNP) | VAF 10/228 reads (4%) | catalogued as COSV101012525; called by muse, mutect2
- DOCK3 | c.1566C>G p.L522= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV56518041, COSV99809893; called by muse, mutect2, varscan2
- FAM135A | c.3792C>T p.L1264= (on ENST00000370479 / NM_001351599.1; = p.L1051= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs775088489, COSV99525399; called by mutect2, varscan2
- GABRA2 | c.90C>A p.I30= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV100733935, COSV100734858; called by muse, mutect2, varscan2
- GATA3 | c.1320C>A p.T440= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV100650857, COSV60521687, COSV99062036; called by muse, mutect2, varscan2
- GRIA2 | c.2334C>G p.G778= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV99643355; called by muse, mutect2, varscan2
- INTS14 | c.1359G>A p.L453= (on ENST00000313182 / NM_001366360.2; = p.L374= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV99970932; called by muse, mutect2, varscan2
- JAKMIP2 | c.96C>T p.D32= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as COSV99507620; called by muse, mutect2, varscan2
- KDM2A | c.3297C>G p.L1099= | Silent (SNP) | VAF 75/176 reads (43%) | catalogued as COSV58189671, COSV58191279; called by muse, mutect2, varscan2
- KLHDC7B | c.1365C>A p.T455= (on ENST00000395676; = p.T1096= on NM_138433.5) | Silent (SNP) | VAF 77/201 reads (38%) | catalogued as COSV101192898; called by muse, mutect2, varscan2
- KRT23 | c.54C>T p.A18= | Silent (SNP) | VAF 43/160 reads (27%) | catalogued as rs778206822, COSV99266139; called by muse, mutect2, varscan2
- LRP4 | c.5427C>T p.I1809= | Silent (SNP) | VAF 65/164 reads (40%) | catalogued as rs763024440, COSV66136938; called by muse, mutect2, varscan2
- MACF1 | c.20496C>T p.V6832= (on ENST00000372915; = p.V4877= on NM_012090.5) | Silent (SNP) | VAF 19/486 reads (4%) | catalogued as COSV99242139; called by muse, mutect2
- MEAK7 | c.630G>C p.L210= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV100640374; called by muse, mutect2
- MLF1 | c.126C>T p.L42= | Silent (SNP) | VAF 10/192 reads (5%) | catalogued as rs1341278783, COSV100575960; called by muse, mutect2
- MUC16 | c.30414C>T p.S10138= | Silent (SNP) | VAF 38/61 reads (62%) | catalogued as rs1164917555, COSV67492629; called by muse, mutect2, varscan2
- MYBL2 | c.1269C>T p.V423= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV99406092; called by muse, mutect2
- NKG7 | c.426C>A p.L142= | Silent (SNP) | VAF 12/185 reads (6%) | catalogued as COSV99389797; called by muse, mutect2
- NKX6-2 | c.603C>A p.T201= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs548659147, COSV100888323; called by muse, mutect2, varscan2
- OR2A25 | c.252C>A p.L84= | Silent (SNP) | VAF 14/203 reads (7%) | catalogued as COSV101376326, COSV101376353, COSV68717317; called by muse, mutect2
- OR52H1 | c.588C>T p.I196= (on ENST00000322653; = p.I202= on NM_001005289.1) | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV100497271; called by muse, mutect2
- OR6M1 | c.696G>A p.Q232= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as COSV100484029; called by muse, mutect2, varscan2
- OR9Q1 | c.864C>A p.I288= | Silent (SNP) | VAF 58/159 reads (36%) | catalogued as COSV100109531; called by muse, mutect2, varscan2
- PPP1R26 | c.1140A>T p.T380= | Silent (SNP) | VAF 54/157 reads (34%) | catalogued as COSV100778009; called by muse, mutect2, varscan2
- PSAPL1 | c.297C>A p.P99= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100040364; called by muse, mutect2, varscan2
- RASSF5 | c.348G>A p.P116= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as COSV100795078; called by muse, mutect2, varscan2
- RBP3 | c.2592G>T p.R864= | Silent (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- ROCK1 | c.1305G>T p.L435= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV101296262; called by muse, mutect2, varscan2
- SERPINB3 | c.1134C>A p.T378= | Silent (SNP) | VAF 103/350 reads (29%) | catalogued as COSV99379646, COSV99379686; called by muse, mutect2, varscan2
- SH3BGR | c.186C>G p.V62= | Silent (SNP) | VAF 19/424 reads (4%) | catalogued as COSV100374387; called by muse, mutect2
- SH3RF2 | c.1881G>A p.V627= | Silent (SNP) | VAF 22/192 reads (11%) | catalogued as COSV100767633; called by muse, mutect2, varscan2
- SOCS6 | c.855G>C p.V285= | Silent (SNP) | VAF 11/350 reads (3%) | catalogued as COSV101205667; called by muse, mutect2
- STPG1 | c.852C>T p.F284= (on ENST00000337248 / NM_001199013.2; = p.F237= on NM_178122.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/180 reads (11%) | catalogued as COSV99133777; called by muse, mutect2, varscan2
- TMEM107 | c.189C>T p.L63= (on ENST00000437139 / NM_183065.4; = p.L69= on NM_032354.5) | Silent (SNP) | VAF 11/200 reads (6%) | catalogued as COSV100328689; called by muse, mutect2
- UNKL | c.444G>T p.R148= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100061275; called by muse, mutect2, varscan2
- USH2A | c.11721T>A p.A3907= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as COSV100230771; called by muse, mutect2
- WARS1 | c.1371G>A p.V457= | Silent (SNP) | VAF 7/196 reads (4%) | catalogued as COSV100690059; called by muse, mutect2
- WDR7 | c.4128A>T p.S1376= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as COSV99588849; called by muse, mutect2, varscan2
- ZNF592 | c.1716C>T p.L572= | Silent (SNP) | VAF 28/316 reads (9%) | catalogued as rs779211960, COSV100245723; called by muse, mutect2
- CAPS2 | c.1670-2687G>T | Intron (SNP) | VAF 40/110 reads (36%) | catalogued as rs1176165535, COSV100157458; called by muse, mutect2, varscan2
- KDM2B | c.126+745G>C | Intron (SNP) | VAF 16/308 reads (5%) | catalogued as COSV100997274; called by muse, mutect2
- MTRNR2L6 | chr7:142671219 C>T | 3'Flank (SNP) | VAF 21/163 reads (13%) | called by muse, mutect2, varscan2
- XIRP2 | c.*841G>C | 3'UTR (SNP) | VAF 11/99 reads (11%) | catalogued as COSV99739588; called by muse, mutect2, varscan2
